Gene-level copy-number profile of tumor specimen TCGA-MB-A8JK-01A from TCGA case TCGA-MB-A8JK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.8 years (18,177 days).
Specimen TCGA-MB-A8JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.df99a19a-c11f-4969-a654-74edb515893d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MB-A8JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0835736f-cd6c-44d7-a7c4-71bb76a304c3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 950; copy number 2: 16,840; copy number 3: 22,855; copy number 4: 14,106; copy number 5: 3,042; copy number 6: 312; copy number 7: 1,497; copy number 8: 81; copy number 9: 31; copy number 10: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MB-A8JK-01A-11D-A36I-01): tumor purity 0.64, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,013,660–248,919,946, 50 genes: OR2L5, Y_RNA, OR2L2, Y_RNA, OR2L3, OR2T32P, OR2L13, OR2M1P, OR2M5, OR2M2, OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr13:47,307,082–47,459,234, 2 genes: GNG5P5, RN7SL700P.
- chr13:48,232,612–48,711,226, 14 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.
- chr13:109,101,261–109,101,919, 1 gene: MYO16-AS2.
- chr17:9,764,186–9,822,071, 5 genes: AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3.
- chr17:10,383,144–10,623,886, 1 gene (within-gene range 0–3): MYHAS.
- chr17:10,492,307–10,623,036, 3 genes: MYH1, MYH2, AC005323.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,635 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–182,414,815, 1,253 genes, copy number 7 (broad region; genes not listed).
- chr1:182,433,893–182,442,362, 2 genes, copy number 7: AL139344.1, TEDDM2P.
- chr2:124,025,287–124,989,325, 6 genes, copy number 9 (within-gene range 3–9): CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P.
- chr2:140,103,583–140,221,485, 4 genes, copy number 9: LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,683,888, 3 genes, copy number 9: AC092156.1, MIR7157, COPRSP1.
- chr3:6,490,460–10,977,981, 87 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:11,006,098–11,019,224, 1 gene, copy number 7 (within-gene range 3–7): SLC6A1-AS1.
- chr6:60,281,444–63,230,110, 18 genes, copy number 9 (within-gene range 4–9): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2.
- chr12:66,767–991,190, 25 genes, copy number 10: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:1,151,810–1,153,059, 1 gene, copy number 10: HTR1DP1.
- chr12:7,919,230–8,662,888, 52 genes, copy number 7 (within-gene range 3–7): SLC2A3, AC006511.6, Y_RNA, AC006511.1, AC006511.4, HSPD1P12, AC006511.2, FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A, FAM66C, DEFB109F, AC092111.2, AC092111.1, FAM90A1, ALG1L10P, FAM86FP, LINC02449, AC092745.5, ENPP7P5, AC092745.4, LINC00937, AC092745.2, AC092745.1, AC092745.3, RPS3AP43, AC092865.4, AC092865.3, AC092865.2, OR7E140P, OR7E148P, OR7E149P, CLEC6A, AC092865.1, RNU6-275P, CLEC4D, SUPT4H1P2, CLEC4E, AC092746.1, Y_RNA, AC092184.1, AICDA, AC092184.2, HADHAP2, MFAP5.
- chr12:13,238,582–13,982,002, 9 genes, copy number 8 (within-gene range 3–8): AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr13:33,355,206–36,920,765, 40 genes, copy number 7 (within-gene range 3–7): AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1.
- chr17:20,956,682–22,706,703, 62 genes, copy number 7 (broad region; genes not listed).
- chr19:12,833,951–12,874,952, 1 gene, copy number 8 (within-gene range 4–8): MAST1.
- chr19:12,875,209–14,408,725, 71 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
